FM case AD1807 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract.
https://portal.gdc.cancer.gov/cases/617c4969-b96f-4a39-9248-12ff6c207444

Female, 52.2 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the biliary tract; metastasis biopsied or resected from the appendix. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
